Somatic mutation profile of tumor specimen 0DHTEG from CCDI case PBBURI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.5 years (6,038 days).
Specimen 0DHTEG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c658951f-4538-4e87-a387-3f294475d94f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHTDR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9a509c3-3ca9-4531-946c-c2ea01a41095

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Silent 1, Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OGT | c.1251T>A p.C417* | Nonsense Mutation (SNP) | VAF 52/357 reads (15%) | called by muse, mutect2, varscan2
- SEC14L1 | c.1508A>T p.K503I | Missense Mutation (SNP) | VAF 63/352 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC4A4 | c.330G>A p.T110= (on ENST00000264485 / NM_001098484.3; = p.T66= on NM_003759.4) | Silent (SNP) | VAF 115/542 reads (21%) | catalogued as rs772559707; called by muse, mutect2, varscan2
- LMBR1L | c.1083-79G>A | Intron (SNP) | VAF 5/25 reads (20%) | catalogued as rs1280523624; called by muse, mutect2, varscan2
- SCFD1 | c.1629+22C>A | Intron (SNP) | VAF 22/173 reads (13%) | called by muse, mutect2, varscan2
